Somatic mutation profile of tumor specimen TCGA-27-2518-01A (aliquot TCGA-27-2518-01A-01D-1494-08) from TCGA case TCGA-27-2518, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 52.4 years (19,130 days).
Specimen TCGA-27-2518-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4af3b068-319c-4373-b268-611cd779543c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-27-2518-10A (Blood Derived Normal), aliquot TCGA-27-2518-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21ae3762-ea7b-4b65-adc3-11f8f6406d83

The open-access MAF lists 55 somatic variants for this specimen: 35 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 18, Nonsense Mutation 3, 3'Flank 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL4 | c.1703A>G p.N568S | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV66059480; called by muse, mutect2, varscan2
- CCND2 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 8/107 reads (7%) | catalogued as COSV54221841; called by muse, mutect2
- CLCN1 | c.2508G>C p.K836N | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV58367570, COSV58369066; called by muse, mutect2, varscan2
- CLEC4M | c.1057C>T p.R353W | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs778660811, COSV50216842; called by muse, mutect2, varscan2
- CMTM2 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV51747960; called by muse, mutect2, varscan2
- CORO2A | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762368061, COSV59662066; called by muse, mutect2, varscan2
- CP | c.918C>A p.N306K | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.389); catalogued as COSV52829128; called by muse, mutect2, varscan2
- DNAH3 | c.255G>C p.L85F | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as COSV54504579, COSV54555352; called by muse, mutect2
- DPP10 | c.1306C>A p.Q436K | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.065); catalogued as COSV59665978; called by muse, mutect2, varscan2
- GLT1D1 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 57/360 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs765354223, COSV55878595, COSV55880001; called by muse, mutect2, varscan2
- GRIN2A | c.3953G>A p.R1318Q | Missense Mutation (SNP) | VAF 33/273 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs149745535; ClinVar: likely benign; called by muse, mutect2, varscan2
- HNRNPCL1 | c.322T>A p.S108T | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.074); catalogued as COSV58610042; called by muse, mutect2, varscan2
- KLF11 | c.179G>T p.R60I | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV59939991; called by muse, mutect2, varscan2
- KRT34 | c.1028C>T p.T343M | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs143564749; called by muse, mutect2, varscan2
- LAPTM4A | c.127A>T p.M43L | Missense Mutation (SNP) | VAF 69/220 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV51531834; called by muse, mutect2, varscan2
- NRIP1 | c.1231C>A p.P411T | Missense Mutation (SNP) | VAF 37/370 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.603); catalogued as COSV59655234; called by muse, mutect2
- OR4P4 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 78/303 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as rs753984758, COSV58920714; called by muse, mutect2, varscan2
- OR51B6 | c.834C>A p.H278Q | Missense Mutation (SNP) | VAF 33/290 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV66512254; called by muse, mutect2, varscan2
- OR6Q1 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 28/376 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs774364450, COSV56932207; called by muse, mutect2
- PRPF40B | c.1471C>T p.R491C (on ENST00000380281; = p.R485C on NM_012272.3) | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756035810, COSV56057538; called by muse, mutect2, varscan2
- RAB38 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 74/251 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.013); catalogued as COSV54711799; called by muse, mutect2, varscan2
- ROR2 | c.671C>T p.S224L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV65218333; called by muse, mutect2, varscan2
- SALL4 | c.1513G>A p.G505S | Missense Mutation (SNP) | VAF 103/370 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs200920825, COSV53849939; called by muse, mutect2, varscan2
- SAMD7 | c.1115G>C p.G372A | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59417153, COSV59418053; called by muse, mutect2, varscan2
- SERPINB13 | c.19G>A p.V7I | Missense Mutation (SNP) | VAF 75/209 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs139825462; called by muse, mutect2, varscan2
- SEZ6L2 | c.2293G>A p.A765T (on ENST00000308713 / NM_001114099.3; = p.A695T on NM_012410.4) | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs375292147, COSV100435739, COSV58097371; called by muse, mutect2, varscan2
- SLC22A11 | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.12); catalogued as rs754156235, COSV57251883; called by muse, mutect2, varscan2
- SPEG | c.2725G>A p.V909M | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1358749184, COSV56663531; called by muse, mutect2, varscan2
- SPHKAP | c.4741A>T p.K1581* (on ENST00000392056 / NM_001142644.2; = p.K1552* on NM_030623.3) | Nonsense Mutation (SNP) | VAF 21/264 reads (8%) | catalogued as COSV60869195; called by muse, mutect2
- STYX | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 16/252 reads (6%) | catalogued as rs931639551, COSV63462613; called by muse, mutect2
- TAFA1 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1055625351, COSV72037141; called by muse, mutect2, varscan2
- TUBA8 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.98); catalogued as rs774116816, COSV57812378; called by muse, mutect2, varscan2
- VARS2 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 142/456 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52557809, COSV99461583; called by muse, mutect2, varscan2
- WDR64 | c.3155G>A p.R1052H | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs185903348, COSV100843775, COSV63792811; called by muse, mutect2, varscan2
- ZGPAT | c.872-2A>C p.X291_splice | Splice Site (SNP) | VAF 98/297 reads (33%) | catalogued as COSV58873440; called by muse, mutect2, varscan2
- ADM | c.49C>T p.L17= | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as COSV53402726; called by muse, mutect2, varscan2
- AHNAK2 | c.2979C>T p.A993= | Silent (SNP) | VAF 193/593 reads (33%) | catalogued as COSV60908451; called by muse, mutect2, varscan2
- CHST1 | c.1170G>A p.S390= | Silent (SNP) | VAF 29/165 reads (18%) | catalogued as rs1487470192, COSV57321861; called by muse, mutect2, varscan2
- FRG2C | c.129A>G p.K43= | Silent (SNP) | VAF 54/470 reads (11%) | called by muse, mutect2, varscan2
- GFPT2 | c.1830C>T p.V610= | Silent (SNP) | VAF 101/322 reads (31%) | catalogued as rs1346170822, COSV53806515; called by muse, varscan2
- GFPT2 | c.1692C>G p.T564= | Silent (SNP) | VAF 97/297 reads (33%) | catalogued as COSV53806527; called by muse, varscan2
- HPCAL4 | c.126C>T p.I42= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs758441133, COSV65716040; called by muse, mutect2, varscan2
- HPS3 | c.1200G>A p.A400= | Silent (SNP) | VAF 14/139 reads (10%) | catalogued as rs377368442, COSV56052782; called by muse, mutect2, varscan2
- IL5RA | c.603T>G p.T201= | Silent (SNP) | VAF 8/176 reads (5%) | catalogued as COSV56521203; called by muse, mutect2
- LEMD3 | c.906C>A p.A302= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV57648590; called by muse, mutect2, varscan2
- NLRP5 | c.189C>T p.Y63= | Silent (SNP) | VAF 60/269 reads (22%) | catalogued as rs543185262, COSV66761926; called by muse, mutect2, varscan2
- NSD3 | c.3042C>T p.G1014= | Silent (SNP) | VAF 100/396 reads (25%) | catalogued as COSV57667084; called by muse, mutect2, varscan2
- PCDHB12 | c.1023C>T p.N341= | Silent (SNP) | VAF 57/155 reads (37%) | catalogued as rs782673787, COSV53393314; called by muse, mutect2, varscan2
- PSG6 | c.519G>A p.P173= | Silent (SNP) | VAF 32/544 reads (6%) | catalogued as rs1065506; called by muse, mutect2
- RALYL | c.429C>T p.H143= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs375364868; called by muse, mutect2, varscan2
- SIGLEC5 | c.1497C>T p.P499= | Silent (SNP) | VAF 51/269 reads (19%) | catalogued as rs141897891; called by muse, mutect2, varscan2
- SLC1A6 | c.1017G>A p.L339= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as COSV55668107; called by muse, mutect2, varscan2
- SLC26A9 | c.1863C>T p.S621= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs375116397, COSV61601460; called by muse, mutect2, varscan2
- AC073310.1 | n.348C>T | RNA (SNP) | VAF 123/516 reads (24%) | catalogued as rs375332788; called by muse, mutect2, varscan2
- FAM153CP | chr5:178055609 C>T | 3'Flank (SNP) | VAF 16/56 reads (29%) | catalogued as rs761082413; called by muse, mutect2, varscan2
